Gene-level copy-number profile of tumor specimen TCGA-FS-A4FD-06A from TCGA case TCGA-FS-A4FD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 45.8 years (16,726 days).
Specimen TCGA-FS-A4FD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.2d67d564-41f9-47fb-a1de-f1d14279d4ef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A4FD-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/baa76990-6a07-48eb-b58f-14823b01798b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,868; copy number 2: 38,943; copy number 3: 9,992; copy number 4: 859; copy number 5: 561; copy number 6: 1,330; copy number 7: 20; copy number 9: 87; copy number 15: 160.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A4FD-06A-11D-A25P-01): tumor purity 0.82, ploidy 2.21, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,158 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–6 (broad region; genes not listed).
- chr17:52,862,121–52,987,652, 2 genes, copy number 5: LINC02089, LINC02876.
- chr17:66,302,613–66,810,743, 5 genes, copy number 6 (within-gene range 4–6): PRKCA, RN7SL735P, PRKCA-AS1, RNU6-928P, RNA5SP445.
- chr17:67,070,444–68,551,319, 50 genes, copy number 5–7 (within-gene range 3–7): HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A.
- chr20:42,685,404–64,313,132, 567 genes, copy number 5–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,482. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
